FM case AD16782 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/d79aa0fc-e4bb-4eb0-901c-9a3564713bb6

Male, 40.3 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
